Somatic mutation profile of tumor specimen TCGA-2G-AAGG-01A (aliquot TCGA-2G-AAGG-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGG, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 20.1 years (7,330 days).
Specimen TCGA-2G-AAGG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54115958-a2e2-47c9-b1c9-bdee0c315cab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGG-10A (Blood Derived Normal), aliquot TCGA-2G-AAGG-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb10ec65-cf4d-410f-8ad2-2eeaba4e525e

The open-access MAF lists 35 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, Nonsense Mutation 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHEX | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs886041363, CM971163; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHRM3 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs200967479, COSV55083513; called by muse, mutect2, varscan2
- EHBP1L1 | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs749884229; called by muse, mutect2, varscan2
- EML2 | c.1823G>T p.R608L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs967203926, COSV55600230; called by muse, mutect2
- GRB7 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 30/127 reads (24%) | catalogued as COSV58449900; called by muse, mutect2, varscan2
- LPA | c.4314G>T p.R1438S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV60308568; called by muse, mutect2, varscan2
- POLK | c.2529-5T>C | Splice Region (SNP) | VAF 191/371 reads (51%) | catalogued as rs1397576597; called by muse, mutect2, varscan2
- PRDM9 | c.2581G>A p.V861I | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.709); catalogued as rs780084938, COSV99689931; called by muse, mutect2, varscan2
- SURF4 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.567); catalogued as rs782238598, COSV64339157; called by muse, mutect2, varscan2
- TCEANC | c.949C>T p.L317F (on ENST00000380600 / NM_001297563.2; = p.L347F on NM_152634.4) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV59039392; called by muse, mutect2
- YRDC | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs138070077; called by muse, mutect2
- ZCCHC2 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.824); catalogued as rs747971040; called by muse, mutect2, varscan2
- ADCY2 | c.1261G>T p.V421F | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ARHGAP10 | c.2316C>G p.N772K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP45 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CR1 | c.5252G>A p.S1751N | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GALNT1 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- NISCH | c.240C>G p.N80K | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPHP3 | c.2777T>G p.L926W | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OSBPL7 | c.1534G>C p.E512Q | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFDN4 | c.89C>G p.T30R | Missense Mutation (SNP) | VAF 111/373 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PNMA6A | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 15/319 reads (5%) | called by muse, mutect2
- PRKDC | c.7755A>T p.E2585D | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RPAP1 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- SHROOM3 | c.378C>A p.S126R | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- SLC12A7 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC24A2 | c.1109A>G p.Y370C | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TFRC | c.1335C>A p.S445R | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2
- ADAM28 | c.42T>G p.V14= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs547338346; called by muse, mutect2, varscan2
- C17orf99 | c.687C>A p.P229= | Silent (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- ITPR1 | c.738G>A p.E246= | Silent (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- MAB21L4 | c.375C>T p.T125= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs773072905, COSV100278454; called by muse, mutect2, varscan2
- POM121L12 | c.534G>T p.L178= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- TRIM51 | c.834G>T p.L278= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV55265211; called by muse, mutect2
- SUOX | c.*35C>A | 3'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as rs1454104008; called by muse, mutect2
